Somatic mutation profile of tumor specimen 0DJILS from CCDI case PBBXBK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 9.3 years (3,406 days).
Specimen 0DJILS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a64342a1-d602-405a-ad63-6168aa0b91dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJIKW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1d86f80c-9d7b-4372-b302-cd1ca3080dbc

The open-access MAF lists 9 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Missense Mutation 3, 3'UTR 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBLN5 | c.727G>A p.V243I | Missense Mutation (SNP) | VAF 41/1058 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs976720995, COSV50902583; called by muse, mutect2
- AGTR1 | c.880A>G p.N294D | Missense Mutation (SNP) | VAF 81/1440 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAGEB6B | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 253/693 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CCL4 | c.219C>T p.V73= | Silent (SNP) | VAF 34/1258 reads (3%) | called by muse, mutect2
- OR4C46 | c.729G>A p.T243= | Silent (SNP) | VAF 52/938 reads (6%) | catalogued as rs781550990; called by muse, mutect2
- XIRP1 | c.60G>A p.E20= | Silent (SNP) | VAF 60/1138 reads (5%) | catalogued as COSV61138657; called by muse, mutect2
- PPIF | c.*94C>T | 3'UTR (SNP) | VAF 76/217 reads (35%) | catalogued as rs529848344; called by muse, mutect2, varscan2
- TASOR | chr3:56621484 G>A | 3'Flank (SNP) | VAF 136/342 reads (40%) | called by muse, mutect2, varscan2
- TMTC2 | c.*46T>C | 3'UTR (SNP) | VAF 38/637 reads (6%) | catalogued as rs1163943547; called by muse, mutect2
